Somatic mutation profile of tumor specimen MP2PRT-PAVHYJ-TBP1-A (aliquot MP2PRT-PAVHYJ-TBP1-A-1-0-D-A83Q-36) from MP2PRT case MP2PRT-PAVHYJ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (630 days).
Specimen MP2PRT-PAVHYJ-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) df835e12-6085-4f31-8d74-ec838b5c1aa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHYJ-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHYJ-NB1-A-1-0-D-A83Q-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8d5c9d5-c7b1-4a18-b714-328e9d2d194b

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2, Frame Shift Ins 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KATNB1 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 83/275 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as rs782135998; called by muse, mutect2, varscan2
- OR4E2 | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 61/235 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs750842276, COSV57732338; called by muse, mutect2, varscan2
- SLC6A15 | c.573T>A p.T191= | Splice Region (SNP) | VAF 28/138 reads (20%) | catalogued as COSV57026601; called by muse, varscan2
- CCDC188 | c.689_690insTTGCGGCG p.E231Cfs*48 | Frame Shift Ins (INS) | VAF 92/368 reads (25%) | called by mutect2, varscan2
- CREBBP | c.3128_3129insCC p.E1044Qfs*13 | Frame Shift Ins (INS) | VAF 61/278 reads (22%) | called by mutect2, pindel, varscan2
- OPLAH | c.642G>A p.T214= | Silent (SNP) | VAF 154/620 reads (25%) | catalogued as rs781862668; called by muse, varscan2
- PCDHB2 | c.1836G>A p.T612= | Silent (SNP) | VAF 121/848 reads (14%) | called by muse, mutect2, varscan2
